Somatic mutation profile of tumor specimen TCGA-E3-A3E5-01A (aliquot TCGA-E3-A3E5-01A-11D-A20C-08) from TCGA case TCGA-E3-A3E5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.5 years (20,993 days).
Specimen TCGA-E3-A3E5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86c28f0-2641-4e32-8ad5-95bde2db5298.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E3-A3E5-10A (Blood Derived Normal), aliquot TCGA-E3-A3E5-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9906cbf-0423-483f-a448-1e65893cb591

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ASCC3 | c.869T>C p.I290T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs754514662, COSV61225887; called by muse, mutect2, varscan2
- EIF3F | c.654-2A>T p.X218_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV59141244; called by muse, mutect2, varscan2
- GAPVD1 | c.2554C>T p.H852Y (on ENST00000394104; = p.H879Y on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs757750913, COSV52920247; called by muse, mutect2, varscan2
- HDLBP | c.2223C>G p.F741L | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60492170; called by muse, mutect2, varscan2
- LAMC2 | c.3023A>G p.K1008R | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV51452567; called by muse, mutect2, varscan2
- LDHA | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV57038736, COSV57042906; called by muse, mutect2, varscan2
- TCAP | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54092378; called by muse, mutect2, varscan2
- XYLB | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 80/161 reads (50%) | catalogued as rs774058695, COSV52911574; called by muse, mutect2, varscan2
- DMAC2 | c.497_498del p.L166Qfs*72 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | called by pindel, varscan2
- HEATR5B | c.5496A>G p.T1832= | Silent (SNP) | VAF 66/185 reads (36%) | catalogued as COSV51849101; called by muse, mutect2, varscan2
